CGCI case BLGSP-71-19-00114 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6c957218-bef4-48c6-9c8d-0352dd8d6077

Demographics
Sex at birth: male; Race: white; Age at index: 3 years; Vital status: Dead; Days to death: 2,660 days (7.3 years); Cause of death: Cardiovascular Disorder, NOS.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Small intestine, NOS; Classification of tumor: primary; Age at diagnosis: 3.0 years (1,114 days); Year of diagnosis: 1995; Method of diagnosis: Excisional Biopsy; Ann Arbor pathologic stage: Stage III; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 2,652 days (7.3 years); Ann Arbor extranodal involvement: Yes; Burkitt lymphoma clinical variant: Sporadic, pediatric; Max tumor bulk site: Other; Sites of involvement: Kidney, NOS / Tonsil.
   Pathology details: Bone marrow malignant cells: No; Lymph node involved site: Cervical, NOS.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis.

Follow-up (3 entries)
- Days to follow up: 1,505 days (4.1 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Small intestine, NOS; Days to progression: 1,505 days (4.1 years); Evidence of recurrence type: Biopsy with Histologic Confirmation.
- Days to follow up: 2,652 days (7.3 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 0.

Molecular and laboratory tests
- BCL2 (IHC): Positive.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Positive.

Other clinical attributes
- Day 0: Weight: 27.5 kg; Height: 131 cm; BMI: 16.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-19-00114-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample BLGSP-71-19-00114-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Biospecimen anatomic site: Small Bowel; Preservation method: Frozen; Days to sample procurement: 1,505 days (4.1 years); Method of sample procurement: Excisional Biopsy; Tissue collection type: Retrospective.
  Slide BLGSP-71-19-00114-02A-01-CS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 85; Percent monocyte infiltration: 15; Percent neutrophil infiltration: 0.
- Sample BLGSP-71-19-00114-16A: Sample type: Mononuclear Cells from Bone Marrow Normal; Tissue type: Normal; Specimen type: Mononuclear Cells from Bone Marrow; Preservation method: Frozen; Days to sample procurement: 0 days; Method of sample procurement: Bone Marrow Aspirate; Tissue collection type: Retrospective.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Cause of death other: Pulmonary embolus and congenital bicuspid aortic valve with evidence of both valvular stenosis and incompetence; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: No; New tumor event diagnosis indicator: Yes.
- Primary pathology: Histologic diagnosis: diffuse small non-cleaved per medical record; Extranodal site involvement: 3; Extranodal involvment other: right tonsil and right adenoid; Lymph nodes examined: No.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: cervical.
- Stage record, Ann arbor: B symptoms present indicator: No.
- New tumor event: New tumor event type: Distant Metastasis; New tumor event site other: small intestine.
